TCGA case TCGA-ZT-A8OM — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Other and ill-defined sites; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d9816402-1073-4b19-ba16-1c7e7c00fbb3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Thymoma, type A, NOS: ICD-O-3 morphology code: 8581/1; ICD-10 code: C76.1; Tissue or organ of origin: Thorax, NOS; Site of resection or biopsy: Anterior mediastinum; Classification of tumor: primary; Age at diagnosis: 73.7 years (26,923 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIb; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,398 days (3.8 years).
   Pathology details: Consistent pathology review: Yes.

Follow-up (2 entries)
- Days to follow up: 1,398 days (3.8 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 172 cm; BMI: 23.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZT-A8OM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 60 mg.
  Slide TCGA-ZT-A8OM-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZT-A8OM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZT-A8OM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: IIb.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type A.
- Primary pathology: History myasthenia gravis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,398 days; disease-specific survival: no event (censored), 1,398 days; progression-free interval: no event (censored), 1,398 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZT-A8OM-01A-11D-A427-01): tumor purity 0.96, ploidy 2, whole-genome doublings 0.
